CPTAC case C3L-07965 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cbbf7057-ee9e-40ef-8d09-03112bdfb16a

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 69.4 years (25,349 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic N: N3c; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIID; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 286 days; Progression or recurrence: no; Days to last follow up: 286 days; Clark level: IV; Tumor focality: Unifocal.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 1.08 cm; Lymph node involvement: Positive; Lymph nodes positive: 12; Lymph nodes tested: 29; Margin status: Involved.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 286 days; Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07965-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -29 days; Initial weight: 611 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07965-21: Section location: Trunk; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3L-07965-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -29 days; Method of sample procurement: Blood Draw.
